Somatic mutation profile of tumor specimen TCGA-2G-AAG9-01A (aliquot TCGA-2G-AAG9-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAG9, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 25.2 years (9,210 days).
Specimen TCGA-2G-AAG9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48ce033d-7e81-4cf9-a6df-5788a7dd1b29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAG9-10A (Blood Derived Normal), aliquot TCGA-2G-AAG9-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/680f6e37-ef71-477f-a075-cb3e49164580

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Splice Region 1, Intron 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55502236; called by muse, mutect2, varscan2
- PTPN23 | c.1615G>C p.A539P | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV55545776; called by muse, mutect2, varscan2
- RDH13 | c.459G>C p.L153F (on ENST00000415061 / NM_001145971.2; = p.L82F on NM_138412.4) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99401579; called by muse, mutect2, varscan2
- SPHKAP | c.3113T>C p.F1038S | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV60871314; called by muse, mutect2, varscan2
- ULK1 | c.2800C>A p.Q934K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs766989906, COSV58860141; called by muse, mutect2, varscan2
- ZNF490 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs747519338; called by muse, mutect2, varscan2
- AMHR2 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC18 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPC2 | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNS | c.446A>G p.K149R | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFT172 | c.3468T>C p.G1156= | Splice Region (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- KDM2A | c.260+3_260+6del p.X87_splice | Splice Site (DEL) | VAF 18/86 reads (21%) | called by pindel, varscan2
- LETMD1 | c.348G>C p.K116N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- PIM2 | c.451A>C p.I151L | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CARD10 | c.2331G>A p.E777= | Silent (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- DDX6 | c.1141C>A p.R381= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV50590234; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1864C>A p.R622= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV58563360; called by muse, mutect2, varscan2
- UBFD1 | c.303C>T p.F101= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs781726179; called by muse, mutect2, varscan2
- ZNF84 | c.1647G>A p.G549= | Silent (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- IL34 | c.-19G>T | 5'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- MYL7 | c.194-75T>C | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
